Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A3CF, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A3CF-06A (Metastatic).

[page 1 of 2]
DIAGNOSIS
Patient ID -

(A) **LEFT SUPERFICIAL FEMORAL LYMPH NODES, LYMPHADENECTOMY:**
METASTATIC MELANOMA TO THREE OF FIFTEEN LYMPH NODES (3/15).
LARGEST TUMOR DEPOSIT SIZE: 23.0 X 13.0 MM (AS MEASURED ON THE SLIDE).
LOCATION: SUBCAPSULAR AND INTRAPARENCHYMAL
EXTRACAPSULAR EXTENSION PRESENT

(B) **LEFT INGUINAL CANAL, EXCISION:**
Mature adipose tissue, consistent with lipoma. Clinical-pathologic correlation is necessary.

(C) **LEFT ILIAC LYMPH NODES, LYMPHADENECTOMY:**
METASTATIC MELANOMA TO ONE OF FIVE LYMPH NODES (1/5).
LARGEST TUMOR DEPOSIT SIZE: 2.0 X 2.0 MM
LOCATION: SUBCAPSULAR AND INTRAPARENCHYMAL
No extracapsular extension is identified.

ICD-O-3

Melanoma, NOS 8720/3
Site: lymph nodes, femoral
C77.4

(D) **LEFT OBTURATOR LYMPH NODES, LYMPHADENECTOMY:**
METASTATIC MELANOMA TO ONE OF TWO LYMPH NODES (1/2).
LARGEST TUMOR DEPOSIT SIZE: 0.4 X 0.2 MM.
LOCATION: INTRAPARENCHYMAL
No extracapsular extension is identified.

lw 10/3/11

(E) **LEFT HEEL, SKIN ELLIPSE:**
SKIN AND SUBCUTANEOUS WITH INVASIVE MELANOMA, ACRAL-LENTIGINOUS TYPE, CLARK LEVEL V,
BRESLOW THICKNESS 9.0 MM, LYMPHOVASCULAR INVASION AND ULCERATION (5 MM) PRESENT.
Final assessment of margins of resection pending additional sections; an addendum report will follow.

(F) **NEW DEEP MARGIN, EXCISION:**
Fibroadipose tissue, no tumor identified.

(G) **ADDITIONAL LATERAL SKIN, SKIN ELLIPSE:**
Skin and subcutaneous tissue, no tumor identified in the representative sections examined.

(H) **ADDITIONAL ILIAC LYMPH NODE, LYMPHADENECTOMY:**
One lymph node, no tumor identified (0/1).

GROSS DESCRIPTION

(A) **LEFT SUPERFICIAL FEMORAL LYMPH NODES** - A 21.0 x 14.0 x 14.0 x 1.4 cm fatty tissue. There is a 5.5 x 3.0 x 1.5 cm firm nodule and a smaller firm nodule, 1.8 x 1.5 x 1.3 cm. Both nodules have a fleshy pink to gray-tan cut surfaces. Tissue from the nodules is submitted for tissue bank. Specimen is dissected for lymph nodes and multiple lymph nodes are found ranging in size from 2.5 x 0.7 x 0.5 to 0.5 x 0.3 x 0.2 cm and are entirely submitted.

SECTION CODE: A1, representative section from the largest nodule grossly involved by tumor; A2, representative section from the second largest nodule grossly involved by tumor; A3, one possible lymph node; A4, one possible lymph node; A5, one possible lymph node; A6, one possible lymph node; A7, one possible lymph node; A8, A9, one possible lymph node; A10, two possible lymph nodes; A11, two possible lymph nodes; A12, one possible lymph node; A13, two possible lymph nodes; A14, four possible lymph nodes; A15, six possible lymph nodes; A16, two possible lymph nodes; A17, one possible lymph node; A18, two possible lymph nodes.

(B) **LEFT INGUINAL CANAL LIPOMA** - A 2.5 x 2.5 x 0.8 cm fatty tissue with a partially hemorrhagic cut surface, entirely submitted in cassettes B1-B4.

(C) **LEFT ILIAC LYMPH NODES** - Multiple fragments of fatty tissue measuring in aggregate 7.5 x 5.0 x 1.5 cm. Dissection reveals multiple possible lymph nodes ranging from 0.8 up to 3.8 cm in their greatest dimension. Possible lymph nodes are entirely submitted in cassettes.

SECTION CODE: C1, one sectioned possible lymph node; C2, one sectioned possible lymph node; C3, C4, one sectioned possible lymph node; C5, C6, one sectioned possible lymph node; C7-C9, one sectioned possible lymph node.

[page 2 of 2]
(D) LEFT OBTURATOR LYMPH NODES - A single fragment of a fatty tissue measuring 5.5 x 2.5 x 1.2 cm. Dissection reveals two possible lymph nodes ranging from 1.8 up to 2.9 cm in their greatest dimension. Possible lymph nodes are entirely submitted in cassettes.

SECTION CODE: D1 and D2, one sectioned possible lymph node; D3-D5, one sectioned possible lymph node.

(E) WLE MELANOMA LEFT HEEL - A portion of white-tan skin and underlying fibroadipose tissue, 5.5 x 4.5 x 1.8 cm with short stitch at proximal margin and long stitch at anterior margin. A well circumscribed raised white-tan tumor, 2.5 x 1.7 x 0.6 cm is identified on the skin surface and the lesion is 2.0 cm to the closest anterior margin. The anterior margin inked blue, posterior margin inked orange. The specimen serially sectioned from proximal to distal. Cut surface reveals the tumor invades into the deep soft tissue, 0.7 cm in maximal depth. The tumor is 0.5 cm to the closest deep margin.

SECTION CODE: E1, shaved proximal margin, ink side up; E2, shaved distal margin, ink side up; E3, shaved anterior margin, ink side up; E4, shaved posterior margin, ink side up; E5, E6, tumor with closest deep margin.

(F) NEW DEEP MARGIN - A piece of fibroadipose tissue, 2.0 x 1.3 x 0.5 cm with stitch at true margin. The true margin inked blue. The specimen serially sectioned and entirely submitted in F

(G) ADDITIONAL LATERAL SKIN - A strip of a grossly unremarkable tan skin and underlying tissue measuring 15.0 x 1.0 x 1.5 cm. Cut surface of the soft tissue is unremarkable. Representative sections are submitted in cassettes G1 and G2.

(H) ADDITIONAL ILIAC NODE - A single possible lymph node measuring 0.8 cm in its greatest dimension. Bisected and entirely submitted in cassette H.

CLINICAL HISTORY

Melanoma.

SNOMED CODES

T-C4000, T-02860, M-87203, M-87206

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration"

3. These tests have not been

Entire report and diagnosis completed by:

Source: NCI Genomic Data Commons file 9ff23477-a77b-46ae-8670-fe6fc56e7bc3 (TCGA-D3-A3CF.47574957-9E10-4D8A-96DB-858C4792A4A8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).